Somatic mutation profile of tumor specimen 0D9W6A from CCDI case PBBHYD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain stem; Age at diagnosis: 1.9 years (690 days).
Specimen 0D9W6A: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ca312c0f-0061-4fab-a814-2a5d1ebf62ec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D9W6B (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/404cdba7-727f-4b24-aef0-8d102a2d0262

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COG5 | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 88/277 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as rs868060358; called by muse, mutect2, varscan2
- EHMT1 | c.3418G>A p.V1140M | Missense Mutation (SNP) | VAF 110/426 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770731320, COSV71777963; called by muse, mutect2, varscan2
- KIF12 | c.536C>T p.S179F (on ENST00000640217; = p.S41F on NM_138424.1) | Missense Mutation (SNP) | VAF 26/930 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs1332012030; called by muse, mutect2
- NPHS1 | c.120C>A p.N40K | Missense Mutation (SNP) | VAF 28/637 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
